Surgical pathology report (de-identified scan), TCGA case TCGA-BR-4361, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-4361-01A (Primary Tumor).

STOMACH TISSUE CHECKLIST. Specimen type: Gastrectomy. Tumor Site: Not specified. Tumor configuration: Ulcerating. Tumor size: 11 cm in diameter. Histologic type: Adenocarcinoma. Histologic grade: Poorly differentiated. Extent of invasion: Liver. Lymph nodes: 2 nodes negative for malignancy. Margins – Proximal margin: Not specified. Distal margin: Not specified. Omental (radial) margin: Not specified. Lymphatic invasion: Not specified. Venous invasion: Not specified. Perineural invasion: Not specified. Additional pathologic findings: Not specified. Comments: None.

Source: NCI Genomic Data Commons file cbae144b-ecaf-4d40-8e1e-d0f2ef227016 (TCGA-BR-4361.90734FA8-E5FF-46FE-9260-C565AB3E2836.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).